Somatic mutation profile of tumor specimen ALCH-B4CH-TTP1-B (aliquot ALCH-B4CH-TTP1-B-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4CH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.1 years (24,491 days).
Specimen ALCH-B4CH-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ead1201-17b0-4751-94a9-e3a02fe09f1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4CH-NB1-A (Blood Derived Normal), aliquot ALCH-B4CH-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61a62276-8240-4d05-9b96-d249460af5b4

The open-access MAF lists 48 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 4, Intron 2, Frame Shift Del 1, 5'Flank 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 1692/2237 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AMBN | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 44/268 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as rs770433471, COSV59825700, COSV99069877; called by muse, mutect2, varscan2
- ANO2 | c.94C>T p.Q32* (on ENST00000356134 / NM_001278597.3; = p.Q36* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as rs1422191798; called by muse, mutect2, varscan2
- DENND4B | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs577416893; called by muse, varscan2
- EVPL | c.5260C>T p.R1754C | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); catalogued as rs763141538, COSV56911545; called by muse, mutect2, varscan2
- GP1BA | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 101/486 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as rs534164809; called by muse, mutect2, varscan2
- MYH4 | c.4733G>T p.R1578L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs761755212; called by muse, mutect2, varscan2
- MZB1 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760353425; called by muse, mutect2, varscan2
- PCDHB7 | c.1278G>C p.L426F | Missense Mutation (SNP) | VAF 29/480 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.247); catalogued as COSV50830323, COSV99177127; called by muse, mutect2
- PID1 | c.86A>C p.K29T | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV62477429; called by muse, mutect2, varscan2
- RBM10 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 175/319 reads (55%) | catalogued as COSV61309929, COSV61312978; called by muse, mutect2, varscan2
- RFX5 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV51838136; called by muse, mutect2, varscan2
- SLC28A2 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs375534708; called by muse, mutect2, varscan2
- SPATC1 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 32/478 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs868947855; called by muse, mutect2
- TTC29 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); catalogued as rs374599032, COSV100283525; called by muse, mutect2, varscan2
- ACSL5 | c.817A>G p.I273V (on ENST00000354273; = p.I329V on NM_016234.3) | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CTNND2 | c.864G>C p.E288D | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, varscan2
- CUL5 | c.1636T>G p.S546A | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DIP2B | c.1206+1G>A p.X402_splice | Splice Site (SNP) | VAF 45/211 reads (21%) | called by muse, mutect2, varscan2
- DNAJC13 | c.353_355delinsTT p.K118Ifs*11 | Frame Shift Del (DEL) | VAF 46/142 reads (32%) | called by pindel, varscan2*
- DTHD1 | c.878G>T p.G293V (on ENST00000456874; = p.G128V on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FXR1 | c.1767T>A p.D589E | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL12B | c.784T>A p.W262R | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JRKL | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 62/223 reads (28%) | called by muse, varscan2
- KBTBD7 | c.1176C>G p.D392E | Missense Mutation (SNP) | VAF 85/379 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAT2A | c.907A>G p.K303E | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MICAL2 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 79/349 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PDE6C | c.1080C>G p.N360K | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPIG | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF17 | c.1441T>C p.C481R | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- SLC38A4 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SUGCT | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TARDBP | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 29/320 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2
- TEX13C | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 126/304 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.28); called by muse, varscan2
- ZNF717 | c.2118G>T p.M706I | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CABP2 | c.132C>T p.G44= | Silent (SNP) | VAF 25/125 reads (20%) | called by muse, mutect2, varscan2
- CD101 | c.2157C>T p.S719= | Silent (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- FOXRED2 | c.954C>T p.L318= | Silent (SNP) | VAF 49/226 reads (22%) | catalogued as rs990091525; called by muse, varscan2
- FOXRED2 | c.864C>T p.I288= | Silent (SNP) | VAF 56/284 reads (20%) | called by muse, varscan2
- LIMA1 | c.531C>T p.I177= | Silent (SNP) | VAF 48/237 reads (20%) | called by muse, mutect2, varscan2
- NWD1 | c.1410G>A p.S470= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs749508047, COSV60340158; called by muse, mutect2, varscan2
- PCDHGA11 | c.1887A>G p.T629= | Silent (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- PGGT1B | c.396A>G p.L132= | Silent (SNP) | VAF 72/297 reads (24%) | called by muse, mutect2, varscan2
- SLC7A7 | c.369C>T p.S123= | Silent (SNP) | VAF 57/232 reads (25%) | called by muse, mutect2, varscan2
- BNC2 | chr9:16870678 C>T | 5'Flank (SNP) | VAF 32/232 reads (14%) | catalogued as rs758071618, COSV101033693; called by muse, mutect2, varscan2
- CFAP77 | c.-5C>A | 5'UTR (SNP) | VAF 15/120 reads (13%) | called by muse, varscan2
- EGFR | c.2284-47C>T | Intron (SNP) | VAF 429/570 reads (75%) | called by muse, mutect2, varscan2
- TNPO2 | c.-13-79C>T | Intron (SNP) | VAF 8/105 reads (8%) | catalogued as rs978316229; called by muse, mutect2
